Somatic mutation profile of tumor specimen 0DLPZE from CCDI case PBBXIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.6 years (5,691 days).
Specimen 0DLPZE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee3488e8-84d4-4252-864a-4f8dacad5906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLQ00 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfb94714-24e4-4df9-b63f-b8c63b583bf6

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCRL3 | c.1583del p.A528Dfs*7 | Frame Shift Del (DEL) | VAF 40/340 reads (12%) | called by mutect2, varscan2
- FCRL3 | c.1582G>T p.A528S | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by mutect2, varscan2
- HNRNPC | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 177/656 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PLEC | c.4906T>G p.L1636V (on ENST00000322810 / NM_201380.4; = p.L1526V on NM_000445.5) | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- OBSCN | c.18662-2712G>C | Intron (SNP) | VAF 90/305 reads (30%) | called by muse, mutect2, varscan2
- PKDCC | c.1034+49G>A | Intron (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
